Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6452, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6452-01A (Primary Tumor).

[page 1 of 2]
STOMACH TISSUE CHECKLIST			
Specimen type:	Gastrectomy		
Tumor site:	Stomach		
Tumor size:	9.5 x 4 x 1.2 cm		
Tumor features:	Exophytic (polypoid)		
Histologic type:	Adenocarcinoma		
Histologic grade:	Poorly differentiated		
Tumor extent:	Adjacent structures (specify) - lesser omentum		
Lymph nodes:	0/5 positive for metastasis (0/5)		
Lymphatic invasion:	Not specified		
Venous invasion:	Not specified		
Perineural invasion:	Not specified		
Margins:	Not specified		
Evidence of neo-adjuvant treatment:	Not specified		
Additional pathologic findings:	Not specified		
Comments:	None		

Specimen type: Gastrectomy
Tumor site: Stomach
Tumor size: 9.5 x 4 x 1.2 cm
Tumor features: Exophytic (polypoid)
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Adjacent structures (specify) - lesser omentum
Lymph nodes: 0/5 positive for metastasis (0/5)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

SECRET

Source: NCI Genomic Data Commons file 567acfdc-e5f9-4d18-8362-c2733f4ee7eb (TCGA-BR-6452.2B5608F1-C4A1-4901-99B0-D23ECDCE3B8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).